Somatic mutation profile of tumor specimen TCGA-EJ-7312-01B (aliquot TCGA-EJ-7312-01B-21D-A32B-08) from TCGA case TCGA-EJ-7312, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 58.3 years (21,292 days).
Specimen TCGA-EJ-7312-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9d6ebe2a-48d8-46bf-a05c-36d7fa7fdf99.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-7312-10A (Blood Derived Normal), aliquot TCGA-EJ-7312-10A-01D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2fae2f10-c083-40b3-843a-adae955f5588

The open-access MAF lists 26 somatic variants for this specimen: 18 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 7, Nonsense Mutation 3, Frame Shift Del 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACCSL | c.1091C>A p.S364Y | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101122338; called by muse, mutect2, varscan2
- ATG3 | c.749A>G p.H250R | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99344465; called by muse, mutect2, varscan2
- CACNA2D4 | c.1594G>A p.G532S | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99766797; called by muse, mutect2, varscan2
- CDH23 | c.6869C>T p.T2290M | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.928); catalogued as rs370912192; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GOLGB1 | c.2787G>T p.K929N | Missense Mutation (SNP) | VAF 60/249 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.607); catalogued as COSV100511681, COSV61461317; called by muse, mutect2, varscan2
- ITCH | c.1191T>G p.Y397* (on ENST00000262650 / NM_001257137.3; = p.Y356* on NM_031483.7 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 49/97 reads (51%) | catalogued as COSV99393341; called by muse, mutect2, varscan2
- KLF12 | c.1118G>T p.G373V | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100888739; called by muse, mutect2, varscan2
- LRCH1 | c.1036A>G p.S346G | Missense Mutation (SNP) | VAF 55/192 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV100244167; called by muse, mutect2, varscan2
- LRIF1 | c.1361C>A p.T454N | Missense Mutation (SNP) | VAF 67/213 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.323); catalogued as COSV100870950; called by muse, mutect2, varscan2
- NAV3 | c.553C>T p.Q185* | Nonsense Mutation (SNP) | VAF 36/130 reads (28%) | catalogued as COSV99896912; called by muse, mutect2, varscan2
- OR52L1 | c.580C>A p.H194N | Missense Mutation (SNP) | VAF 62/220 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100176411, COSV59988064; called by muse, mutect2, varscan2
- PCDHB12 | c.790G>A p.V264I | Missense Mutation (SNP) | VAF 104/290 reads (36%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.171); catalogued as rs782027801, COSV53400379; called by muse, mutect2, varscan2
- SYNE1 | c.1309G>A p.E437K (on ENST00000367255 / NM_182961.4; = p.E444K on NM_033071.3) | Missense Mutation (SNP) | VAF 134/410 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.864); catalogued as COSV99584044; called by muse, mutect2, varscan2
- TEX13A | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 62/86 reads (72%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV100782221, COSV61183333; called by muse, mutect2, varscan2
- TNS3 | c.2582G>A p.R861H | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs958026760, COSV60786219, COSV60790280; called by muse, mutect2, varscan2
- ACSS3 | c.1479del p.K493Nfs*2 | Frame Shift Del (DEL) | VAF 49/133 reads (37%) | called by mutect2, varscan2
- KRTAP9-8 | c.417C>A p.C139* | Nonsense Mutation (SNP) | VAF 21/222 reads (9%) | called by muse, mutect2
- TRIM28 | c.839+2dup p.X280_splice | Splice Site (INS) | VAF 51/166 reads (31%) | called by mutect2, pindel, varscan2
- ABCA9 | c.561T>G p.A187= | Silent (SNP) | VAF 17/67 reads (25%) | catalogued as COSV100383652; called by muse, mutect2, varscan2
- ACSS2 | c.1971C>T p.T657= | Silent (SNP) | VAF 31/64 reads (48%) | catalogued as COSV53623465; called by muse, mutect2, varscan2
- CLEC4A | c.462C>T p.F154= | Silent (SNP) | VAF 37/89 reads (42%) | catalogued as rs1015524617, COSV57563099; called by muse, mutect2, varscan2
- CSMD1 | c.1602C>T p.P534= (on ENST00000520002; = p.P533= on NM_033225.6) | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as rs775892572, COSV100143249, COSV59301218; called by muse, mutect2
- DLG2 | c.1932C>T p.F644= | Silent (SNP) | VAF 38/189 reads (20%) | catalogued as COSV54636376, COSV99720783; called by muse, mutect2, varscan2
- PCNT | c.8181A>G p.S2727= | Silent (SNP) | VAF 5/100 reads (5%) | catalogued as COSV100856188; called by muse, mutect2
- STAC | c.198C>T p.S66= | Silent (SNP) | VAF 46/121 reads (38%) | catalogued as rs751057328, COSV56213615, COSV99830965; called by muse, mutect2, varscan2
- SPATA13 | c.290-5354A>T | Intron (SNP) | VAF 18/34 reads (53%) | catalogued as COSV100542575; called by muse, mutect2, varscan2
